Somatic mutation profile of tumor specimen MP2PRT-PAVRLF-TMP1-A (aliquot MP2PRT-PAVRLF-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVRLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,493 days).
Specimen MP2PRT-PAVRLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d44cb6d3-ed20-405b-8763-98993509df18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRLF-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37ba73a7-b74f-4d00-aafb-347f9772261c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs374544349, COSV59390123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD15 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1031016731; called by muse, mutect2
- ADGRL2 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CAMK4 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- H2AC6 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- KANSL1 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KANSL1 | c.349T>A p.S117T | Missense Mutation (SNP) | VAF 32/614 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- OR2T12 | c.672G>A p.L224= | Silent (SNP) | VAF 418/824 reads (51%) | called by muse, mutect2, varscan2
